Clinical report (de-identified scan), EXCEPTIONAL_RESPONDERS case ER-ABV2, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders), specimen ER-ABV2-TTM1-A (Metastatic).

[page 1 of 6]
RUN DATE: [REDACTED] -1
RUN TIME: [REDACTED]
RUN USER: [REDACTED]

Specimen Inquiry
PCI User [REDACTED] Lab Database: [REDACTED]

PATIENT: [REDACTED] ACCT #: [REDACTED] LOC: [REDACTED] U [REDACTED]
AGE/SX: [REDACTED] ROOM: [REDACTED] RE [REDACTED]
REG DR: [REDACTED] DOB: [REDACTED] BPD: [REDACTED] DTS: -10
STATUS: REG-SDC TLOC: [REDACTED]

-9

Spec #: [REDACTED] Received: [REDACTED] Status: [REDACTED] Reg#: [REDACTED]
Spec Type: SURGICAL Subm Dr: [REDACTED]

Tissues: LYMPH NODE, NOS - Right cervical lymph node

Lymphadenopathy, deep jugular node

The specimen consists of a lymph node which measures 1.3 x 0.8 x 0.6 cm. The lymph node is serially sectioned and a portion of the tissue is submitted for flow cytometry. One portion is submitted for frozen tissue and the remaining tissue is submitted for permanent sections in blocks 1-3.

Dictated by: [REDACTED]

Reviewed are three H&E stained slides. Sections contain a lymph node extensively replaced by poorly differentiated carcinoma composed of large, highly pleomorphic cells growing in a syncytial arrangement with large zones of central necrosis. Some of the cells contain vacuolization consistent with intracytoplasmic mucin. There are also a few poorly formed lumina. Extranodal extension is present. Immunoperoxidase stains for cytokeratin 7, cytokeratin 20, thyroid transcription factor and estrogen receptor were performed on block 2 with appropriately staining controls. The carcinoma is strongly positive for cytokeratin 7 and negative for cytokeratin 20. A significant percentage of cells shows nuclear reactivity for thyroid transcription factor consistent with a pulmonary primary. Estrogen receptor expression is negative. The controls stain appropriately.

LYMPH NODE, RIGHT DEEP JUGULAR, EXCISION:
1. METASTATIC, POORLY DIFFERENTIATED NON-SMALL CELL CARCINOMA CONSISTENT WITH ADENOCARCINOMA, SEE COMMENT.

COMMENT: The carcinoma cells are positive for thyroid transcription factor which is most consistent with a pulmonary primary.

** CONTINUED ON NEXT PAGE **

[page 2 of 6]
SPECIMEN NO. 0000000000

RECEIVED

Specimen:

Received:

-9

signed

(signature on file)

-8

** END OF REPORT **

[page 3 of 6]
Initial Scar,

Name: [REDACTED]
Phys: [REDACTED]
DOB: [REDACTED] Age: [REDACTED] Sex: [REDACTED]
Acct: [REDACTED] Loc: XRAY
Exam Date: [REDACTED] Status: [REDACTED]
Unit No: [REDACTED] +8

RADIOLOGY REPORT

Exams: [REDACTED] PT/TUMOR IMAGE PET/CT SKULL-THI

CHARGES: FDG X 1

PET SCAN:

Exam Diagnosis: LUNG CA
Symptoms: SAME

Following the intravenous administration of F18 as FDG, tomographic images were obtained over the body from the skull base to the knees. Simultaneous CT imaging was carried out for anatomic correlation and attenuation correction.

There is marked increase in glucose uptake in multiple masses in the mediastinum. These include bulky areas of adenopathy or disease in the subcarinal, right hilar, paratracheal, and both scalene node regions. By history, this is adenocarcinoma rather than lymphoma; I do not see a peripheral pulmonary mass, but this might have originated close to the right hilum.

There are no abnormalities elsewhere about the chest and no abnormalities below the diaphragm.

IMPRESSION: Bulky mediastinal and scalene adenopathy with very high levels of glucose uptake. This is most likely cancer. From an imaging standpoint it would be most consistent with lymphoma, but given the history of adenocarcinoma, possibly lung, the best candidate for a primary source would be in the right hilum.

+8 Taken: [REDACTED]
+8 Dictated: [REDACTED]
+9 Signed: [REDACTED]

CC: [REDACTED]

[page 4 of 6]
Scan prior to
taxotere /avastin

Radiology Consultation Report

Name: [REDACTED]

DOB: [REDACTED]

Home: [REDACTED]

Exam Date: [REDACTED]

Room: [REDACTED]

+477

Ord: [REDACTED]

Fam: [REDACTED]

MRN: [REDACTED]

Status: Outpatient

Pregnant: [REDACTED]

Accession: [REDACTED]

Radiologist: [REDACTED]

CPT: [REDACTED]

Exam: NM TUMOR IMAGE PET CT SKULL THIGH

R.T.: [REDACTED]

EXAMDX: Lung Ca restaging

Radiopharmaceutical agent: F-18 FDG 18.4 mCi.

Technique: PET CT images were acquired from the skull base to the knees.
Unenhanced CT images were obtained for attenuation correction and anatomic localization.

Comparison: [REDACTED] +344

Findings: There are numerous bilateral pulmonary nodules, predominately less than 1 cm, which are essentially new since last exam. The largest measures 11 mm and is located in the right upper lobe anteriorly and has a maximum SUV of 4.9. A few of the other pulmonary nodules also exhibit low level glucose uptake. Abnormal uptake is also noted within the fatty areas of the neck, compatible with brown fat. No other abnormal glucose uptake is identified.

Impression:

1. Numerous small bilateral pulmonary nodules, essentially all new, with the largest within the right upper lobe having a maximum SUV of 4.9. Findings are worrisome for progression of metastatic disease. Alternately, could represent an infectious etiology.

Electronically Signed By: [REDACTED]

[page 5 of 6]
Scan showing CR
to taxotere/avastin

Radiology Consultation Report

Name: [REDACTED]
DOB: [REDACTED]

Home: [REDACTED]

Exam Date: [REDACTED]
Room: [REDACTED]

+636

Ord: [REDACTED]
Fam: [REDACTED]

MRN: [REDACTED]

Status: Outpatient

Pregnant: N

Accession: [REDACTED]

Radiologist: [REDACTED]

CPT: [REDACTED]

Exam: NM TUMOR IMAGE PET CT SKULL THIGH
R.T.: [REDACTED]

EXAMDX: Lung Ca Restaging

Comparison: [REDACTED] +632

Procedure: Flourine-18 was administered intravenously as flourodeoxyglucose (FDG). Positron emission tomography was carried out from the skull base to the knees. Simultaneous CT imaging was carried out for attenuation correction and anatomic correlation.

Findings: There is normal distribution of tracer about the body today. There is physiologic glucose uptake in the heart and background of the liver, mediastinum, and vascular structures. Physiologic urinary excretion is noted. There is some moderate uptake in the lateral wall of the stomach similar to that seen earlier; I believe this is a physiologic as well.

The focal area of abnormality seen previously in the para-aortic region of the medial left lung is no longer present.

IMPRESSION: NORMAL STUDY, WITHOUT EVIDENCE OF ACTIVE CANCER AT THIS TIME.

Electronically Signed By: [REDACTED]

[page 6 of 6]
Latest scan

Radiology Consultation Report

Name:
DOB:
Home:

Exam Date: +1789
Room:

Ord:
Fam:

MRN:

Status: Outpatient

Pregnant: N

Exam: NM TUMOR IMAGE PET CT
SKULL THIGH

Accession:

R.T.:
Ref#:

Radiologist:
CPT:

EXAMDX: Lung Restaging

INDICATION: LUNG CANCER RESTAGING.

+1420

+867

COMPARISON: COMPARISON PET CT AND

PROCEDURE: Flourine-18, 15.5 mCi was administered intravenously as flourodeoxyglucose (FDG). Positron emission tomography was carried out from the skull base to the knees. Simultaneous CT imaging was carried out for attenuation correction and anatomic correlation.

PET findings:

There is physiologic metabolic activity throughout the body. The mild amount of uptake at the posterior margin of the superior sternum on previous study demonstrates essentially physiologic activity on today's study without CT correlate. There are stable small nodules in the lung fields measuring 4 mm in the posterior segment right upper lobe on CT image number -189.25, superior aspect lateral segment right middle lobe on image number -231.75, inferior aspect of the right lower lobe on CT image number -244.5, and 5 mm nodule along the medial aspect of the left lower lobe. These appear stable since most recent comparison examination and slightly more pronounced than on study of ~867

Impression:

1. Physiologic metabolic activity.

2. Stable scattered small bilateral pulmonary nodules as detailed above. These are stable since study of however slightly more pronounced than study of +1420

~867

Source: NCI Genomic Data Commons file 43d40948-02dc-4f5c-a68b-6db0fcfeda3d (ER0132 ER-ABV2 Clinical Report_Redacted_Sanitized.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).